Gene-level copy-number profile of tumor specimen TCGA-AA-3869-01A from TCGA case TCGA-AA-3869, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 76.8 years (28,062 days).
Specimen TCGA-AA-3869-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.38ccdcf3-7198-4a02-931c-38440cca3903.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3869-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8cd48e44-d893-4723-8c90-8d08b2fa097c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,735; copy number 3: 29,092; copy number 4: 17,190; copy number 5: 2,629; copy number 6: 497; copy number 7: 115; copy number 8: 117; copy number 9: 16; copy number 10: 268; copy number 11: 42; copy number 13: 95; copy number 23: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-3869-01): tumor purity 0.7, ploidy 3.35, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 677 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:35,313,479–41,065,879, 276 genes, copy number 7–23 (broad region; genes not listed).
- chr20:5,292,388–5,611,006, 13 genes, copy number 8 (within-gene range 6–8): UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1.
- chr20:8,929,895–10,368,776, 16 genes, copy number 9 (within-gene range 6–9): AL445567.1, AL445567.2, Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2.
- chr20:41,024,205–47,188,844, 177 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr20:49,237,946–52,699,472, 76 genes, copy number 10 (broad region; genes not listed).
- chr20:53,397,661–59,397,109, 119 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
